Surgical pathology report (de-identified scan), TCGA case TCGA-92-8065, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - St. Louis, specimen TCGA-92-8065-01A (Primary Tumor).

[page 1 of 4]
Final

**SURGICAL PATHOLOGY REPORT
FINAL WITH ADDENDUM**

Patient Name:

Address:

Gender:

DOB:

Service:

Location:

MRN:

Hospital #:

Patient Type:

Accession #:

Taken:

Received:

Accessioned:

Reported:

Physician(s):

DIAGNOSIS:

LUNG, LEFT LOWER LOBE, BIOPSY (FS1)

- POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA

LYMPH NODE, LEVEL 9, BIOPSY (FS2)

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)

LYMPH NODE, LEVEL 10R, BIOPSY

- NO EVIDENCE OF MALIGNANCY IN ONE LYMPH NODE (0/1)
- CALCIFIED GRANULOMA

LYMPH NODES, LEVEL 7, BIOPSY

- NO EVIDENCE OF MALIGNANCY IN TWO LYMPH NODES (0/2)
- CALCIFIED AND NECROTIZING GRANULOMAS (SEE COMMENT)

LUNG, BRONCHIAL MARGIN, BIOPSY (FS3)

- NO EVIDENCE OF MALIGNANCY

LUNG, LEFT, PNEUMONECTOMY

- INVASIVE POORLY DIFFERENTIATED SQUAMOUS CELL CARCINOMA, 9.5 CM
- CARCINOMA INVADES THROUGH PLEURA
- CARCINOMA INVADES HILAR SOFT TISSUE
- NO DEFINITE LYMPHOVASCULAR INVASION IDENTIFIED
- BRONCHOVASCULAR RESECTION MARGINS FREE OF TUMOR
- PLEURAL ADHESIONS
- SEE SYNOPSIS

LYMPH NODES, PERIBRONCHIAL, PNEUMONECTOMY

- NO EVIDENCE OF MALIGNANCY IN FIVE LYMPH NODES (0/5)

[page 2 of 4]
SURGICAL PATHOLOGY REPORT

Intraoperative Consultation:

"Brought to the frozen section area is a specimen labeled 'left lung,' consisting of a lung measuring 22.5 x 12 x 7.5 cm. A central mass measuring 9 cm in greatest dimension is identified extending into the upper and lower lobes. The tumor is sectioned to show a firm, white lesion extending to the pleura and coming within 0.5 cm of the bronchial/vascular margin. Tissue taken for research study and for tumor banking. Rest for permanent sections," by [REDACTED]

FS1: Left lower lobe mass, biopsy

- "Non-small cell carcinoma, favor squamous cell carcinoma," [REDACTED]

FS2: Level 9 lymph node, biopsy

- "No evidence of malignancy," by [REDACTED]

FS3: Bronchial margin, biopsy

- "Focal squamous metaplasia in salivary glands; no evidence of malignancy," by [REDACTED]

Microscopic Description and Comment:

Microscopic examination substantiates the above cited diagnosis.

AFB and GMS stains for acid fast and fungal organisms are pending on a section of granuloma in a level 7 lymph node. The results will be reported in an addendum.

History:

The patient is a [REDACTED] with a left lung mass. Operative procedure: Left pneumonectomy.

Specimen(s) Received:

A: LEFT LOWER LOBE MASS
B: LYMPH NODE, LEVEL IX
C: LYMPH NODE, X R
D: LYMPH NODE, VII
E: BRONCHIAL MARGIN
F: LUNG, LEFT

Gross Description:

The specimens are received in six formalin-filled containers, each labeled [REDACTED]. The first container is labeled "LLL mass, FS1." It contains a green tissue cassette labeled "FS1" that holds two grey-tan pieces of soft tissue that measure 1.6 x 0.8 x 0.2 cm, in aggregate. Labeled A (FS1). Jar 0.

The second container is labeled "level 9 node, FS2." It contains an unlabeled green tissue cassette that holds two portions of grey-tan lymph node tissue that measure 2.3 x 2.2 x 0.4 cm, in aggregate. Labeled B (FS2). Jar 0.

The third container is labeled "level 10R node." It holds a single grey-tan putative lymph node measuring 1.8 x 1 x 0.5 cm. Bisected to show an unremarkable black-tan interior cut surface. Labeled C, one putative lymph node bisected. Jar 0.

The fourth container is labeled "level 7 lymph node." It holds two putative lymph nodes that measure 1.1 x 1 x 0.4 cm

[page 3 of 4]
SURGICAL PATHOLOGY REPORT

and 0.9 x 0.7 x 0.5 cm, respectively. Bisected to show unremarkable black-tan cut surfaces. Labeled D1 and D2, one putative lymph node in each cassette, bisected. Jar 0.

The fifth container is labeled "bronchial margin, FS3." It contains a green tissue cassette labeled "FS3" that holds a C-shaped portion of yellow-tan bronchial margin that measures 1.5 x 0.4 x 0.2 cm. Labeled E (FS3). Jar 0.

The sixth container is labeled "left lung." It holds a 400 gram left pneumonectomy specimen with two lobes and with dimensions consistent with the intraoperative non-microscopic consultation. The specimen has been previously sectioned to expose a 9.5 x 4.5 x 3.8 cm, white-tan, centrally located mass that bridges both the upper and lower lobes. The pleural surface over this mass at the hilum is stretched and puckered without gross extension of the tumor onto the pleural surface. However, in the left upper lobe, the tumor appears to extend beyond the pleura as a solid mass. Also in this vicinity, and on the medial aspect of the lung, there is an 11 cm portion of fibrous tissue comprising the reflection of the pleura at the mediastinum. The entire pleural surface overlying the tumor is inked blue. The pleura in the uninvolved portions of the lung is grey-tan, wrinkled with scant fibrous adhesions linking the two lobes. At the hilum, a few black-tan peribronchial lymph nodes are identified. The vascular margins are closed off with surgical staples. The staples are removed and the vascular and bronchial resection margins are sampled. The mass is further sectioned to show a firm, white-tan cut surface that is well-circumscribed but unencapsulated. The lesion abuts the bronchial margin of resection. Areas of central cavitation/necrosis are present. The uninvolved lung parenchyma is pink-tan, spongy, and emphysematous. No other localizing lesions are noted. Labeled F1, bronchial and vascular resection margin; F2, peribronchial lymph nodes; F3, tumor in relation to bronchial resection margin (radial section, brief acid decalcification); F4 to F6, tumor in relation to overlying pleura; F7, tumor in relation to large proximal blood vessel; F8 and F9, additional sections of tumor in relation to pleura in left upper lobe (possible extension through pleura); F10, tumor in relation to lung parenchyma; F11, uninvolved upper lobe; F12, uninvolved lower lobe. Jar 3.

SYNOPTIC REPORTING FORM FOR LUNG CARCINOMA

NEOPLASM

A neoplasm is present

HISTOPATHOLOGIC TYPE

The histologic classification of the tumor is squamous cell (epidermoid) carcinoma, keratinizing type

HISTOLOGIC GRADE (G)

The grade of the tumor is poorly differentiated (G3)

TUMOR SIZE

The maximum dimension of the tumor is 9.5 cm

LYMPHATIC INVASION

Lymphatic invasion by tumor is absent (L0)

VENOUS INVASION

Venous invasion by tumor is absent (V0)

ARTERIAL INVASION

Arterial invasion by tumor is absent

PLEURAL INVOLVEMENT

Pleural involvement is present; tumor invades through visceral pleura, without involvement of parietal pleura (PL2)

SAMPLED SPECIMEN MARGINS

The sampled surgical margins are uninvolved by tumor

NON-NEOPLASTIC TISSUE

focal chronic inflammation and fibrosis

[page 4 of 4]
SURGICAL PATHOLOGY REPORT

PRIMARY TUMOR (T)

Tumor > 7 cm or one that directly invades any of the following: parietal pleural (PL3) chest wall (including superior sulcus tumors), diaphragm, phrenic nerve, mediastinal pleura, parietal pericardium; or tumor in the main bronchus (<2 cm distal to the carina* but without involvement of the carina; or associated atelectasis or obstructive pneumonitis of the entire lung or separate tumor nodule(s) in the same lobe) (T3)

REGIONAL LYMPH NODES (N)

No regional lymph node metastasis histologically; no examination for ITC (pN0)
The total number of lymph nodes examined is 9
The total number of metastatically-involved lymph nodes is 0
Extranodal extension by tumor is not applicable; no nodal metastases are present

DISTANT METASTASIS (M)

Distant metastasis cannot be assessed (MX)

STAGE GROUPING

The overall international stage is pT3/N0/MX (Stage IIB)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Addenda/Procedures

Addendum Ordered:

Addendum Complete

Addendum Signed Off

Status: Signed Out

By:

Addendum Comment

The AFB and GMS stains are negative for acid fast and fungal organisms, respectively.

Source: NCI Genomic Data Commons file 33df2b36-4dfc-4c74-ab69-1a1ffab8ca62 (TCGA-92-8065.68423FDB-E1A7-49B8-A531-F27850116A93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).